Gene-level copy-number profile of tumor specimen ALCH-B4BS-TTP1-A from ALCHEMIST case ALCH-B4BS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,011 days).
Specimen ALCH-B4BS-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f9d02351-60f5-4290-903e-191b29bcd371.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4BS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/8476f617-9adf-4473-a630-af51b2f8ef2e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 385; copy number 2: 57,161; copy number 3: 676; copy number 4: 92; copy number 6: 84.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:31,563,166–31,564,076, 1 gene (within-gene range 0–2): HM13-IT1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 84 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:867,630–893,590, 2 genes, copy number 6: MED16, RNU6-9.
- chr19:33,906,352–35,451,767, 82 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 385. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
